FM case AD1433 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/9f948e17-d7f9-4bb3-83f0-8d6d623fe3fe

Male, 51.4 years: diagnosis not reported by GDC; metastasis biopsied or resected from the small intestine. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Metastatic.
